Gene-level copy-number profile of tumor specimen TCGA-61-1915-01A from TCGA case TCGA-61-1915, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 50.4 years (18,424 days).
Specimen TCGA-61-1915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4d1b7d5b-3060-48ed-8a7c-1b51741719b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1915-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e0b39cd-93ea-4b79-9d08-422c01cdc885

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,880; copy number 2: 14,048; copy number 3: 20,293; copy number 4: 14,679; copy number 5: 2,817; copy number 6: 4,877; copy number 7: 593; copy number 8: 106; copy number 9: 242; copy number 10: 214; copy number 11: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1915-01A-01D-0577-01): tumor purity 0.77, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,225 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,487,589–45,570,049, 456 genes, copy number 9–10 (broad region; genes not listed).
- chr1:46,175,073–48,497,736, 70 genes, copy number 11 (broad region; genes not listed).
- chr1:55,329,288–56,070,513, 1 gene, copy number 7 (within-gene range 6–7): AL603840.1.
- chr1:55,868,254–56,996,757, 18 genes, copy number 7: LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1.
- chr6:28,837,869–32,859,851, 339 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:38,168,451–38,640,148, 1 gene, copy number 7 (within-gene range 5–7): BTBD9.
- chr6:38,481,692–44,553,281, 185 genes, copy number 7 (broad region; genes not listed).
- chr12:122,983,480–123,150,015, 1 gene, copy number 8 (within-gene range 6–8): PITPNM2.
- chr12:123,081,384–126,772,519, 105 genes, copy number 8 (broad region; genes not listed).
- chr15:67,974,391–68,257,211, 6 genes, copy number 7 (within-gene range 5–7): AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6.
- chr19:12,880,969–13,880,757, 43 genes, copy number 7: AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D.

Autosomal genes at a single copy (total copy number 1): 1,880. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
